Somatic mutation profile of tumor specimen 0DHQEK from CCDI case PBBUND, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Dead; Primary diagnosis: Medulloblastoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.1 years (1,876 days).
Specimen 0DHQEK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aae94c75-c7f4-4448-a12e-c746f517c19b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DHQDH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a3e6cabf-5208-44be-8b7d-9b7625fd5ac5

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 4, Nonsense Mutation 2, Intron 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SCN9A | c.308C>T p.T103I | Missense Mutation (SNP) | VAF 132/387 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.786); catalogued as rs774058465; called by muse, mutect2, varscan2
- TSC1 | c.1643C>G p.P548R | Missense Mutation (SNP) | VAF 339/679 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.944); catalogued as COSV99036947; called by muse, mutect2, varscan2
- WDR47 | c.1520G>A p.S507N (on ENST00000369962 / NM_001142551.2; = p.S508N on NM_014969.5) | Missense Mutation (SNP) | VAF 143/299 reads (48%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs1251160107, COSV63059012; called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 50/806 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CTDNEP1 | c.321del p.F107Lfs*15 | Frame Shift Del (DEL) | VAF 240/276 reads (87%) | called by mutect2, varscan2
- DSCAML1 | c.4573C>T p.R1525C (on ENST00000321322; = p.R1465C on NM_020693.4) | Missense Mutation (SNP) | VAF 230/541 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FER1L6 | c.5041T>A p.L1681I | Missense Mutation (SNP) | VAF 39/412 reads (9%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- FER1L6 | c.5042T>A p.L1681* | Nonsense Mutation (SNP) | VAF 49/469 reads (10%) | called by muse, mutect2, varscan2
- LGR5 | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 139/330 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- SSH2 | c.1928C>G p.S643* | Nonsense Mutation (SNP) | VAF 24/636 reads (4%) | called by muse, mutect2
- DDN | c.1869C>T p.A623= | Silent (SNP) | VAF 214/454 reads (47%) | called by muse, mutect2, varscan2
- FCRLB | c.531G>A p.E177= | Silent (SNP) | VAF 25/686 reads (4%) | called by muse, mutect2
- GCM2 | c.328C>A p.R110= | Silent (SNP) | VAF 377/610 reads (62%) | catalogued as CM099924, COSV65276268, COSV65276393; called by muse, mutect2, varscan2
- MEP1A | c.465C>T p.H155= | Silent (SNP) | VAF 129/466 reads (28%) | catalogued as rs371616881; called by muse, mutect2, varscan2
- FANCM | c.5717-10G>T | Intron (SNP) | VAF 11/123 reads (9%) | catalogued as rs939194173; ClinVar: likely benign; called by mutect2, varscan2
- MBP | c.140-100T>C | Intron (SNP) | VAF 50/95 reads (53%) | called by muse, mutect2, varscan2
